Somatic mutation profile of tumor specimen TCGA-AB-2898-03A (aliquot TCGA-AB-2898-03A-01W-0733-08) from TCGA case TCGA-AB-2898, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.3 years (25,326 days).
Specimen TCGA-AB-2898-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec02d14e-0396-49b6-9bdc-a4ca282612d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2898-11A (Solid Tissue Normal), aliquot TCGA-AB-2898-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3cdec17-94fb-4ad8-9dcc-cb4d51db292c

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 9, Silent 8, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 51/112 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ATP2C1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.285); catalogued as rs755225326, COSV60753799; called by muse, mutect2, varscan2
- CRISPLD1 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 105/187 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs758100678, COSV51547300; called by muse, mutect2, varscan2
- DNMT3A | c.2478+2T>G p.X826_splice | Splice Site (SNP) | VAF 30/67 reads (45%) | catalogued as rs1327946633, COSV53050793; called by muse, mutect2, varscan2
- DNMT3A | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs774100557, COSV53043935, COSV53053053; called by muse, mutect2, varscan2
- DOP1B | c.1625C>A p.P542H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67693249; called by muse, mutect2, varscan2
- PCDH15 | c.4252G>A p.A1418T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV57303574; called by muse, mutect2, varscan2
- POGLUT1 | c.1121T>A p.V374E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99809922; called by muse, mutect2
- SEL1L2 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53151775; called by muse, mutect2, varscan2
- TET1 | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 102/233 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV65384493; called by muse, mutect2, varscan2
- ASXL2 | c.1972_1973insAG p.A658Efs*142 | Frame Shift Ins (INS) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- MPI | c.466_468del p.E156del | In Frame Del (DEL) | VAF 33/88 reads (38%) | called by pindel, varscan2
- ACAN | c.5268C>T p.S1756= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as rs775729780, COSV61359916; called by muse, mutect2, varscan2
- ARHGAP4 | c.375C>T p.A125= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs782687577, COSV63131930; called by muse, mutect2, varscan2
- CUEDC1 | c.333G>A p.P111= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs771931825, COSV64226376; called by muse, mutect2, varscan2
- EPAS1 | c.948C>T p.Y316= | Silent (SNP) | VAF 106/254 reads (42%) | catalogued as rs774395818, COSV55386276; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM193A | c.2598G>A p.T866= | Silent (SNP) | VAF 95/233 reads (41%) | catalogued as rs773744003, COSV61193584; called by muse, mutect2, varscan2
- MEGF8 | c.6540C>T p.D2180= (on ENST00000251268 / NM_001271938.2; = p.D2113= on NM_001410.3) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs781099770, COSV52083449; called by muse, mutect2, varscan2
- MYO16 | c.399C>T p.A133= | Silent (SNP) | VAF 144/343 reads (42%) | catalogued as COSV51791718; called by muse, mutect2, varscan2
- PTPRN | c.984T>G p.A328= | Silent (SNP) | VAF 86/236 reads (36%) | catalogued as COSV55347553; called by muse, mutect2, varscan2
